Somatic mutation profile of tumor specimen C3L-08164-01 (aliquot CPT0512380006) from CPTAC case C3L-08164, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 56.6 years (20,679 days).
Specimen C3L-08164-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9863492-3aaa-4446-967d-9432372d5ff5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08164-31 (Blood Derived Normal), aliquot CPT0512370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c5070a7-4925-449d-9efd-4b9ef9c6335a

The open-access MAF lists 175 somatic variants for this specimen: 144 protein-altering or splice-affecting, 30 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 30, Nonsense Mutation 5, Frame Shift Del 5, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 63/303 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- A1CF | c.533A>C p.N178T | Missense Mutation (SNP) | VAF 73/360 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1306586727; called by muse, mutect2, varscan2
- A2ML1 | c.4164A>T p.Q1388H | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.198); catalogued as rs777885489; called by muse, mutect2
- ADGRD1 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.166); catalogued as rs141128784; called by muse, mutect2, varscan2
- ADPRHL1 | c.3278G>A p.R1093H | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs373880722; called by muse, mutect2, varscan2
- ASB5 | c.581T>G p.V194G | Missense Mutation (SNP) | VAF 81/308 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV56674543, COSV99642265; called by muse, mutect2, varscan2
- ASTN1 | c.3364T>G p.F1122V | Missense Mutation (SNP) | VAF 26/445 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62502471; called by muse, mutect2
- CDH8 | c.872T>A p.L291H | Missense Mutation (SNP) | VAF 42/291 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV54856481, COSV54868032, COSV54899386; called by muse, mutect2, varscan2
- CEP85 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 61/386 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs570676742, COSV53326756; called by muse, mutect2, varscan2
- CFAP54 | c.4428A>C p.E1476D | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.807); catalogued as COSV61570718; called by muse, mutect2
- CMAS | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as rs756644966; called by muse, mutect2, varscan2
- EMP1 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 29/544 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99916924; called by muse, mutect2
- ERVMER34-1 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs745853061; called by muse, mutect2, varscan2
- GABRA6 | c.518A>C p.K173T | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs1270279109, COSV50877438, COSV99194040; called by muse, mutect2, varscan2
- GBA2 | c.2145T>G p.F715L | Missense Mutation (SNP) | VAF 15/558 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as rs1290397198, COSV62305920; called by muse, mutect2
- GREB1 | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 20/329 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.728); catalogued as rs371609460; called by muse, mutect2
- IGKV3-15 | c.157T>G p.L53V | Missense Mutation (SNP) | VAF 102/461 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as rs768194531; called by muse, mutect2, varscan2
- IL25 | c.272G>T p.R91I | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV100198169; called by muse, mutect2, varscan2
- KANK2 | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 30/584 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs924487064; called by muse, mutect2
- KIR2DL1 | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV52414969; called by muse, mutect2, varscan2
- KLF17 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 60/328 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs776240055, COSV64856913; called by muse, mutect2, varscan2
- KLF8 | c.995A>C p.K332T | Missense Mutation (SNP) | VAF 59/325 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63847919; called by muse, mutect2, varscan2
- L1CAM | c.2105C>G p.P702R | Missense Mutation (SNP) | VAF 13/294 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as rs782568205, COSV62828285; called by muse, mutect2
- LRFN5 | c.2152T>G p.L718V | Missense Mutation (SNP) | VAF 25/264 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1256821553; called by muse, mutect2
- LRP1B | c.11048A>C p.N3683T | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67203413; called by muse, mutect2, varscan2
- LRP1B | c.5081A>G p.K1694R | Missense Mutation (SNP) | VAF 64/284 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV67220150; called by muse, mutect2, varscan2
- LRRC53 | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs1400461676; called by muse, mutect2, varscan2
- LRRIQ3 | c.1561T>G p.L521V | Missense Mutation (SNP) | VAF 39/280 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV63047648; called by muse, mutect2, varscan2
- MAGEC1 | c.3110T>C p.F1037S | Missense Mutation (SNP) | VAF 98/255 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs760755491, COSV53577793; called by muse, mutect2, varscan2
- OR14A2 | c.457T>G p.F153V | Missense Mutation (SNP) | VAF 84/382 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV100825465, COSV100825515; called by muse, mutect2, varscan2
- OR51A7 | c.422T>G p.V141G | Missense Mutation (SNP) | VAF 13/380 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV63788706; called by muse, mutect2
- OR6N2 | c.381T>G p.C127W | Missense Mutation (SNP) | VAF 43/356 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100210570; called by muse, mutect2, varscan2
- OR6P1 | c.582A>C p.Q194H | Missense Mutation (SNP) | VAF 76/413 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV58108666; called by muse, mutect2, varscan2
- PCDHA4 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 28/488 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.19); catalogued as rs1554124492, COSV63542130; called by muse, mutect2
- PCDHB8 | c.692T>G p.I231S | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs374004216; called by muse, mutect2, varscan2
- PLSCR5 | c.609T>G p.D203E | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.137); catalogued as COSV101494510; called by muse, mutect2, varscan2
- PNKD | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 49/424 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as rs200128452; called by muse, mutect2, varscan2
- POP1 | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 47/287 reads (16%) | catalogued as rs1398737207; called by muse, mutect2, varscan2
- POTEC | c.188A>G p.K63R | Missense Mutation (SNP) | VAF 78/580 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs1272652691, COSV100742998, COSV100743266; called by muse, mutect2, varscan2
- PRR27 | c.329del p.P110Rfs*35 | Frame Shift Del (DEL) | VAF 39/321 reads (12%) | catalogued as rs1451549115, COSV100748833; called by mutect2, pindel, varscan2
- PRRX1 | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 70/305 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1272026144, COSV53410909, COSV99509643; called by muse, mutect2, varscan2
- PTPRT | c.1594A>C p.S532R | Missense Mutation (SNP) | VAF 24/840 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as COSV61979883, COSV61996751; called by muse, mutect2
- RAG2 | c.1011A>C p.Q337H | Missense Mutation (SNP) | VAF 80/323 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV57558987; called by muse, mutect2, varscan2
- RMDN1 | c.877A>G p.T293A | Missense Mutation (SNP) | VAF 31/321 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs751865515; called by muse, mutect2, varscan2
- RORA | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.472); catalogued as rs188796486, COSV59546707; called by muse, mutect2, varscan2
- RTL4 | c.126A>C p.Q42H | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV61205698; called by muse, mutect2, varscan2
- SCEL | c.161A>C p.K54T | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV62993374; called by muse, mutect2, varscan2
- SENP1 | c.1907G>T p.W636L | Missense Mutation (SNP) | VAF 44/460 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV99136882; called by muse, mutect2
- SPTLC3 | c.1250T>G p.L417R | Missense Mutation (SNP) | VAF 45/301 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV65463363; called by muse, mutect2, varscan2
- SRRT | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 41/456 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs778464271; called by muse, mutect2
- SYNE1 | c.16547A>C p.E5516A (on ENST00000367255 / NM_182961.4; = p.E5445A on NM_033071.3) | Missense Mutation (SNP) | VAF 34/371 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs199877537, COSV99553104, COSV99576946; called by muse, mutect2
- TAF1L | c.5310A>C p.E1770D | Missense Mutation (SNP) | VAF 70/488 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.986); catalogued as COSV99645040; called by muse, mutect2, varscan2
- TMEM132C | c.2852A>C p.K951T | Missense Mutation (SNP) | VAF 59/448 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV59421132; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1075A>G p.N359D | Missense Mutation (SNP) | VAF 21/369 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs763843514; called by muse, mutect2
- TRAK2 | c.2405T>G p.F802C | Missense Mutation (SNP) | VAF 29/482 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104409291; called by muse, mutect2
- TRIM17 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 48/638 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs774290771; called by muse, mutect2
- TRIM49B | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 104/442 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as COSV60321576, COSV60322163, COSV60324412; called by muse, mutect2, varscan2
- TRIM49C | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 38/557 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV71510527, COSV71511634; called by muse, mutect2
- UNC5C | c.2219A>C p.N740T | Missense Mutation (SNP) | VAF 92/378 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs776961360; called by muse, mutect2, varscan2
- UNC5D | c.2744T>A p.L915H | Missense Mutation (SNP) | VAF 88/522 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99771359; called by muse, mutect2, varscan2
- VAV1 | c.392C>A p.T131N | Missense Mutation (SNP) | VAF 38/480 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs776311282; called by muse, mutect2
- ZNF273 | c.1116A>C p.K372N | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV60397334; called by muse, mutect2, varscan2
- ZNF521 | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.979); catalogued as rs747881763, COSV64127261; called by muse, mutect2, varscan2
- A2M | c.863A>C p.E288A | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- A2ML1 | c.657del p.F219Lfs*19 | Frame Shift Del (DEL) | VAF 35/329 reads (11%) | called by mutect2, pindel, varscan2
- ANKMY1 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 31/369 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- ARHGEF35 | c.1409dup p.L470Ffs*3 | Frame Shift Ins (INS) | VAF 76/407 reads (19%) | called by mutect2, pindel, varscan2
- ASTN1 | c.1606T>C p.Y536H | Missense Mutation (SNP) | VAF 53/324 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRINP2 | c.773T>G p.L258R | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.06); called by muse, mutect2
- CARMIL2 | c.2375A>T p.K792M | Missense Mutation (SNP) | VAF 17/399 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2
- CCDC168 | c.9938C>T p.A3313V | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.079); called by muse, mutect2
- CCDC172 | c.80T>C p.V27A | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); called by muse, mutect2
- CHD4 | c.1991T>G p.L664* (on ENST00000357008 / NM_001363606.2; = p.L677* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 38/195 reads (19%) | called by muse, mutect2, varscan2
- CHD7 | c.6105A>G p.E2035= | Splice Region (SNP) | VAF 56/277 reads (20%) | called by muse, mutect2, varscan2
- CHRM2 | c.455T>C p.F152S | Missense Mutation (SNP) | VAF 34/478 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- COL6A5 | c.1538A>C p.K513T | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- COL6A6 | c.2233C>T p.L745F | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CPEB2 | c.1217C>A p.P406Q | Missense Mutation (SNP) | VAF 116/416 reads (28%) | SIFT tolerated, low confidence (1); called by muse, varscan2
- CSMD1 | c.3169A>G p.R1057G (on ENST00000520002; = p.R1056G on NM_033225.6) | Missense Mutation (SNP) | VAF 82/391 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- CSMD1 | c.1546T>G p.F516V (on ENST00000520002; = p.F515V on NM_033225.6) | Missense Mutation (SNP) | VAF 24/357 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- CTNNA3 | c.2537T>G p.V846G | Missense Mutation (SNP) | VAF 116/574 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CYLC1 | c.896A>C p.E299A | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- DENND5A | c.3778G>C p.V1260L | Missense Mutation (SNP) | VAF 39/351 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- DNAH9 | c.3541C>T p.Q1181* | Nonsense Mutation (SNP) | VAF 29/408 reads (7%) | called by muse, mutect2
- DNER | c.1328G>A p.G443D | Missense Mutation (SNP) | VAF 22/476 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DSEL | c.3061T>G p.L1021V | Missense Mutation (SNP) | VAF 88/503 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EVC2 | c.2504A>C p.K835T | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- FLG2 | c.3532A>G p.S1178G | Missense Mutation (SNP) | VAF 73/438 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXR2 | c.616A>G p.R206G | Missense Mutation (SNP) | VAF 41/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- FRAS1 | c.7463A>C p.K2488T | Missense Mutation (SNP) | VAF 34/440 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.205); called by muse, mutect2
- GOLGA6L2 | c.888G>C p.W296C | Missense Mutation (SNP) | VAF 56/537 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GZMH | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2
- ITGBL1 | c.923A>C p.K308T | Missense Mutation (SNP) | VAF 60/413 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- JAKMIP1 | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 124/560 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- KCNA1 | c.664T>C p.F222L | Missense Mutation (SNP) | VAF 13/484 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2
- KIR3DL3 | c.40T>G p.F14V | Missense Mutation (SNP) | VAF 46/558 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); called by muse, mutect2
- KLC2 | c.1721A>C p.N574T | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- KLHL13 | c.1300T>G p.F434V | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- KMT2A | c.3284C>T p.A1095V | Missense Mutation (SNP) | VAF 96/462 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAP9 | c.1485A>C p.E495D | Missense Mutation (SNP) | VAF 78/349 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MED12L | c.4125T>G p.N1375K | Missense Mutation (SNP) | VAF 23/455 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.027); called by muse, mutect2
- MLH3 | c.4287del p.W1429Cfs*64 (on ENST00000355774 / NM_001040108.2; = p.W1405Cfs*64 on NM_014381.3) | Frame Shift Del (DEL) | VAF 53/293 reads (18%) | called by mutect2, pindel, varscan2
- MROH2A | c.4235G>C p.G1412A | Missense Mutation (SNP) | VAF 44/506 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- MTMR7 | c.1678A>C p.S560R | Missense Mutation (SNP) | VAF 88/415 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTNR1B | c.625T>G p.F209V | Missense Mutation (SNP) | VAF 50/668 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2
- MYEF2 | c.1013T>G p.L338R | Missense Mutation (SNP) | VAF 23/318 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYO18B | c.4624A>T p.R1542W | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAV3 | c.5674A>C p.T1892P (on ENST00000397909 / NM_001024383.2; = p.T1870P on NM_014903.6) | Missense Mutation (SNP) | VAF 23/273 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.475); called by muse, mutect2
- NOX4 | c.1112T>C p.L371P | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- NPAP1 | c.3152T>G p.V1051G | Missense Mutation (SNP) | VAF 42/430 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- OR10A7 | c.599T>A p.L200H | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- OR5B12 | c.446G>A p.C149Y | Missense Mutation (SNP) | VAF 80/347 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PABPC5 | c.112T>G p.F38V | Missense Mutation (SNP) | VAF 137/332 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAPPA2 | c.2194A>G p.I732V | Missense Mutation (SNP) | VAF 71/375 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PCDH11X | c.812T>C p.L271P | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCMTD2 | c.1083del p.K361Nfs*6 | Frame Shift Del (DEL) | VAF 52/340 reads (15%) | called by mutect2, pindel, varscan2
- PCNX1 | c.1559A>C p.K520T | Missense Mutation (SNP) | VAF 33/362 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2
- PHLDB2 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 72/365 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- PLXNA2 | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 36/644 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); called by muse, mutect2
- PRAG1 | c.3771_3793del p.G1258Afs*182 | Frame Shift Del (DEL) | VAF 84/651 reads (13%) | called by mutect2, pindel
- PRKACB | c.753T>G p.I251M | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PXDNL | c.944A>C p.K315T | Missense Mutation (SNP) | VAF 29/405 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2
- RANBP17 | c.1421T>G p.L474R | Missense Mutation (SNP) | VAF 63/304 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- RIMS1 | c.3152A>C p.K1051T | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.398); called by muse, mutect2
- RSBN1L | c.1282A>T p.K428* | Nonsense Mutation (SNP) | VAF 22/208 reads (11%) | called by muse, mutect2, varscan2
- SEZ6L | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SLC1A4 | c.526A>T p.R176* | Nonsense Mutation (SNP) | VAF 24/314 reads (8%) | called by muse, mutect2
- SLC2A10 | c.118T>C p.F40L | Missense Mutation (SNP) | VAF 104/1078 reads (10%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SLC44A5 | c.1408T>C p.F470L | Missense Mutation (SNP) | VAF 39/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SMARCA2 | c.76A>C p.I26L | Missense Mutation (SNP) | VAF 54/520 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); called by muse, mutect2
- SPACA9 | c.395A>C p.N132T | Missense Mutation (SNP) | VAF 44/433 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SPATA31A1 | c.1979A>C p.K660T | Missense Mutation (SNP) | VAF 68/1226 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- SYNE1 | c.13265T>C p.V4422A (on ENST00000367255 / NM_182961.4; = p.V4351A on NM_033071.3) | Missense Mutation (SNP) | VAF 19/430 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2
- THSD7B | c.3814A>C p.S1272R (on ENST00000272643; = p.S1270R on NM_001316349.2) | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TIMD4 | c.635T>G p.L212R | Missense Mutation (SNP) | VAF 12/427 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2
- TOGARAM1 | c.2149T>G p.L717V | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- TRO | c.2798T>C p.L933P | Missense Mutation (SNP) | VAF 93/233 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TSKU | c.655G>C p.V219L | Missense Mutation (SNP) | VAF 121/515 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TSSK1B | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 18/516 reads (3%) | SIFT tolerated (0.43); PolyPhen benign (0.026); called by muse, mutect2
- VPS8 | c.3509A>C p.K1170T (on ENST00000625842 / NM_001349294.1; = p.K1168T on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- XIRP2 | c.6842A>T p.K2281I (on ENST00000628543; = p.K2456I on NM_152381.6) | Missense Mutation (SNP) | VAF 15/384 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2
- ZNF521 | c.2246A>C p.K749T | Missense Mutation (SNP) | VAF 36/456 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF845 | c.1604A>C p.K535T | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZPLD1 | c.1207A>C p.S403R (on ENST00000466937 / NM_001329788.1; = p.S419R on NM_175056.2) | Missense Mutation (SNP) | VAF 15/403 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2
- CACNG6 | c.159G>A p.A53= | Silent (SNP) | VAF 137/714 reads (19%) | catalogued as rs113333594; called by muse, mutect2, varscan2
- CAMK4 | c.660T>C p.P220= | Silent (SNP) | VAF 29/370 reads (8%) | called by muse, mutect2
- CBY3 | c.237T>C p.F79= | Silent (SNP) | VAF 89/667 reads (13%) | catalogued as rs1340960124; called by muse, mutect2, varscan2
- CHRD | c.2820A>G p.P940= | Silent (SNP) | VAF 66/427 reads (15%) | called by muse, mutect2, varscan2
- COL17A1 | c.4023C>T p.I1341= | Silent (SNP) | VAF 87/552 reads (16%) | catalogued as rs1351858225; called by muse, mutect2, varscan2
- DNAH5 | c.3840T>G p.S1280= | Silent (SNP) | VAF 47/252 reads (19%) | catalogued as COSV54211882, COSV54231460; called by muse, mutect2, varscan2
- DUSP10 | c.90T>C p.S30= | Silent (SNP) | VAF 20/442 reads (5%) | called by muse, mutect2
- HOXB9 | c.438C>A p.A146= | Silent (SNP) | VAF 58/506 reads (11%) | catalogued as COSV60817319; called by muse, mutect2, varscan2
- KCNV1 | c.814A>C p.R272= | Silent (SNP) | VAF 90/461 reads (20%) | catalogued as COSV52089305; called by muse, mutect2, varscan2
- LRP1B | c.12064T>C p.L4022= | Silent (SNP) | VAF 72/331 reads (22%) | catalogued as rs185506429; called by muse, mutect2, varscan2
- MAGEB5 | c.289T>C p.L97= | Silent (SNP) | VAF 19/286 reads (7%) | catalogued as COSV66868829; called by muse, mutect2
- MYT1L | c.669A>T p.S223= | Silent (SNP) | VAF 37/487 reads (8%) | called by muse, mutect2
- NLRP13 | c.2427T>C p.A809= | Silent (SNP) | VAF 32/364 reads (9%) | called by muse, mutect2
- OR4K1 | c.904A>C p.R302= | Silent (SNP) | VAF 23/367 reads (6%) | catalogued as rs776170067; called by muse, mutect2
- OR4Q3 | c.138T>C p.I46= | Silent (SNP) | VAF 33/418 reads (8%) | called by muse, mutect2
- OR5L1 | c.435T>G p.A145= | Silent (SNP) | VAF 79/320 reads (25%) | catalogued as COSV61732719, COSV61734643; called by muse, mutect2, varscan2
- PDCD6IP | c.2349G>A p.A783= | Silent (SNP) | VAF 19/470 reads (4%) | catalogued as rs950125626, COSV56241788; called by muse, mutect2
- PGK2 | c.399A>G p.Q133= | Silent (SNP) | VAF 56/620 reads (9%) | catalogued as rs557577912, COSV100505472, COSV59165313; called by muse, mutect2
- PIK3R1 | c.2121C>T p.N707= (on ENST00000521381 / NM_181523.3; = p.N437= on NM_181504.4) | Silent (SNP) | VAF 12/374 reads (3%) | catalogued as rs922311379, COSV57122908; called by muse, mutect2
- PLCL1 | c.2115T>G p.S705= | Silent (SNP) | VAF 28/364 reads (8%) | catalogued as COSV101407234; called by muse, mutect2
- PRKG1 | c.555T>C p.A185= | Silent (SNP) | VAF 63/341 reads (18%) | catalogued as COSV64792974; called by muse, mutect2, varscan2
- RET | c.2187T>G p.T729= | Silent (SNP) | VAF 16/518 reads (3%) | called by muse, mutect2
- RSL1D1 | c.840T>C p.L280= | Silent (SNP) | VAF 52/180 reads (29%) | called by muse, mutect2, varscan2
- SETBP1 | c.123T>A p.T41= | Silent (SNP) | VAF 47/564 reads (8%) | called by muse, mutect2
- SLC17A2 | c.750G>T p.L250= | Silent (SNP) | VAF 58/318 reads (18%) | called by muse, mutect2, varscan2
- SMARCA2 | c.78T>C p.I26= | Silent (SNP) | VAF 54/518 reads (10%) | called by muse, mutect2
- TRPS1 | c.1281T>C p.G427= (on ENST00000220888 / NM_001330599.2; = p.G440= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/410 reads (6%) | catalogued as rs1016917526; called by muse, mutect2
- TTN | c.12307A>C p.R4103= (on ENST00000591111; = p.R4057= on NM_003319.4) | Silent (SNP) | VAF 35/450 reads (8%) | catalogued as COSV100623277, COSV60374857; called by muse, mutect2
- UFD1 | c.225C>T p.D75= | Silent (SNP) | VAF 48/361 reads (13%) | called by muse, mutect2, varscan2
- ZFYVE9 | c.567C>T p.N189= | Silent (SNP) | VAF 25/290 reads (9%) | catalogued as rs1211059341; called by muse, mutect2
- NRSN1 | c.190-4477A>G | Intron (SNP) | VAF 66/353 reads (19%) | called by muse, mutect2, varscan2
